Somatic mutation profile of tumor specimen MMRF_2039_2_BM_CD138pos (aliquot MMRF_2039_2_BM_CD138pos_T1_KHS5U_K15199) from MMRF case MMRF_2039, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.4 years (25,715 days).
Specimen MMRF_2039_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6ec4309-8236-43c0-8834-409a61d744e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2039_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2039_1_PB_CD3pos_C3_KHS5U_L08839; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec1e1ab4-6901-47d9-984b-687f40a13d88

The open-access MAF lists 252 somatic variants for this specimen: 91 protein-altering or splice-affecting, 25 silent, 136 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 81, Missense Mutation 73, Intron 29, Silent 25, 5'UTR 9, Nonsense Mutation 8, 3'Flank 6, RNA 6, 5'Flank 5, Splice Site 5, Splice Region 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABLIM1 | c.1857G>T p.L619F | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs780610190; called by muse, mutect2, varscan2
- ARHGAP26 | c.1301C>G p.S434C | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV50828845; called by muse, mutect2, varscan2
- C2orf73 | c.667C>G p.L223V | Missense Mutation (SNP) | VAF 66/225 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs1484604349; called by muse, mutect2, varscan2
- COL17A1 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1204758676; called by muse, mutect2, varscan2
- CTTNBP2 | c.1144G>C p.E382Q | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as COSV50413012; called by muse, varscan2
- ECT2 | c.961C>G p.L321V (on ENST00000392692 / NM_001349098.2; = p.L290V on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs1420843429, COSV99221444; called by muse, mutect2, varscan2
- ELN | c.1314C>A p.S438= | Splice Region (SNP) | VAF 24/62 reads (39%) | catalogued as COSV52708555; called by muse, mutect2, varscan2
- GABBR2 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1307030320, COSV52320095; called by muse, mutect2, varscan2
- GIPC3 | c.925C>T p.R309W (on ENST00000644946; = p.I304= on NM_133261.3) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as rs748777903, COSV59260277; called by muse, mutect2, varscan2
- GPR158 | c.3322C>T p.R1108C | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs372238950, COSV66267514; called by muse, mutect2, varscan2
- H2BC17 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 66/197 reads (34%) | catalogued as COSV58153674; called by muse, mutect2, varscan2
- HIVEP3 | c.5252G>A p.R1751Q | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746325865, COSV56008983; called by muse, mutect2, varscan2
- IGFLR1 | c.441G>C p.W147C | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.181); catalogued as rs752844952; called by muse, mutect2, varscan2
- IGFLR1 | c.196G>C p.G66R | Missense Mutation (SNP) | VAF 74/200 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1299552912; called by muse, mutect2, varscan2
- IGLL5 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs762998471, COSV73248971, COSV73251039; called by muse, mutect2
- IQCN | c.2344A>G p.N782D | Missense Mutation (SNP) | VAF 60/239 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs768761161; called by muse, mutect2, varscan2
- KCNT2 | c.2762G>C p.G921A | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV54071255; called by muse, mutect2, varscan2
- KMT2B | c.370C>A p.Q124K | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.011); catalogued as rs1471589178; called by muse, mutect2, varscan2
- MTMR11 | c.1124-7C>T | Splice Region (SNP) | VAF 21/86 reads (24%) | catalogued as rs1553767657; called by muse, mutect2, varscan2
- NEK9 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV53131347; called by muse, mutect2, varscan2
- OR6C1 | c.897C>G p.F299L | Missense Mutation (SNP) | VAF 118/410 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.02); catalogued as COSV101110500; called by muse, mutect2, varscan2
- P3H2 | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.449); catalogued as rs549590724; called by muse, mutect2, varscan2
- PCDHB1 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 94/353 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs370733686; called by muse, mutect2, varscan2
- PPFIA2 | c.2921G>C p.R974P | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61045372; called by muse, mutect2, varscan2
- RB1 | c.2236G>T p.E746* | Nonsense Mutation (SNP) | VAF 9/17 reads (53%) | catalogued as CM040265, COSV57314725, COSV57323773; called by muse, mutect2, varscan2
- SBF2 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 23/95 reads (24%) | catalogued as rs1032796987, CM145153, COSV56292176; called by muse, mutect2, varscan2
- SLC26A9 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs754354952; called by muse, mutect2, varscan2
- SLCO1B3 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV53942827; called by muse, mutect2, varscan2
- SPRTN | c.305G>C p.R102T | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV50480396; called by muse, mutect2, varscan2
- STBD1 | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.154); catalogued as COSV99421561; called by muse, mutect2, varscan2
- SYNJ1 | c.2905_2910del p.L969_I970del | In Frame Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs747135111; called by pindel, varscan2
- TOX2 | c.358C>T p.Q120* (on ENST00000358131 / NM_001098798.2; = p.Q69* on NM_032883.3) | Nonsense Mutation (SNP) | VAF 53/196 reads (27%) | catalogued as COSV57882917, COSV57889841; called by muse, mutect2, varscan2
- TTN | c.91430C>T p.S30477L (on ENST00000591111; = p.S23053L on NM_003319.4) | Missense Mutation (SNP) | VAF 60/159 reads (38%) | PolyPhen benign (0.436); catalogued as COSV59984012; called by muse, mutect2, varscan2
- ZBTB32 | c.1222C>A p.Q408K | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.997); catalogued as COSV52892432; called by muse, mutect2, varscan2
- ZNF512B | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.05); catalogued as rs778825361; called by muse, mutect2, varscan2
- AC131160.1 | c.581G>A p.R194K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ARHGAP33 | c.19G>T p.D7Y | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- BEGAIN | c.13A>G p.S5G | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CDK5RAP3 | c.1493C>G p.P498R | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, varscan2
- CFHR5 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.886); called by mutect2, varscan2
- CMYA5 | c.12114T>G p.F4038L | Missense Mutation (SNP) | VAF 55/235 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- CNTLN | c.1364C>G p.S455* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2
- COL4A2 | c.3025+1G>T p.X1009_splice | Splice Site (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- COL9A1 | c.1451G>A p.G484D | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DDX12P | n.819+1G>A | Splice Site (SNP) | VAF 33/197 reads (17%) | called by muse, mutect2, varscan2
- DIPK1C | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- DLGAP4 | c.827C>A p.T276N | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DMTF1 | c.1650+1G>A p.X550_splice | Splice Site (SNP) | VAF 33/105 reads (31%) | called by muse, mutect2, varscan2
- ENTPD5 | c.1066G>C p.E356Q | Missense Mutation (SNP) | VAF 93/217 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- ERICH6B | c.1902G>T p.M634I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- FAM184B | c.2234C>T p.S745F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- GGA1 | c.1613C>G p.S538C | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- GLDC | c.1762G>T p.A588S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- HAUS8 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- HIVEP1 | c.2870C>T p.T957I | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSF5 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.552); called by muse, varscan2
- IGFLR1 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); called by muse, varscan2
- IGFLR1 | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.039); called by muse, varscan2
- INTS1 | c.5426A>G p.Q1809R | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IRF1 | c.851_853+42del p.X284_splice | Splice Site (DEL) | VAF 19/160 reads (12%) | called by mutect2, pindel
- JAKMIP2 | c.2011G>C p.E671Q | Missense Mutation (SNP) | VAF 52/234 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KIR2DS4 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.096); called by muse, varscan2
- KMT2B | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- KMT2B | c.2308C>A p.P770T | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2B | c.7572C>G p.F2524L | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MAGEB17 | c.239C>G p.S80C | Missense Mutation (SNP) | VAF 47/71 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- MGAT5B | c.856-1G>A p.X286_splice | Splice Site (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2, varscan2
- MYCBP2 | c.6043G>C p.D2015H (on ENST00000357337; = p.D2053H on NM_015057.5) | Missense Mutation (SNP) | VAF 49/205 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYH4 | c.1879del p.A627Hfs*33 | Frame Shift Del (DEL) | VAF 48/163 reads (29%) | called by mutect2, varscan2
- MYO1F | c.2965C>A p.L989M | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by mutect2, varscan2
- NFKB2 | c.1927G>T p.E643* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- NPFFR1 | c.268C>A p.L90M | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- NUDT4 | c.360C>G p.F120L | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA10 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PHYKPL | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PLSCR2 | c.334G>A p.E112K (on ENST00000497985 / NM_001199978.1; = p.E39K on NM_020359.2) | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- POLD1 | c.2229dup p.G744Wfs*12 | Frame Shift Ins (INS) | VAF 72/326 reads (22%) | called by mutect2, pindel, varscan2
- PRR7 | c.635C>A p.S212* | Nonsense Mutation (SNP) | VAF 21/127 reads (17%) | called by muse, mutect2, varscan2
- PWWP2A | c.1733C>A p.S578Y | Missense Mutation (SNP) | VAF 86/353 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- RANBP1 | c.386C>G p.A129G | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- SBNO2 | c.688C>A p.P230T | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHOC1 | c.2944G>T p.A982S | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC6A1 | c.64G>T p.V22L | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNX24 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STAM | c.731A>C p.D244A | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNFAIP3 | c.260G>C p.R87P | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- TTC4 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 88/270 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- UBE3A | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- ZBTB32 | c.1007C>G p.S336C | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF347 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by mutect2, varscan2
- ZXDA | c.1718A>G p.D573G | Missense Mutation (SNP) | VAF 16/187 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.053); called by muse, mutect2
- ARHGAP45 | c.1005G>A p.P335= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs745785243; called by mutect2, varscan2
- CBLIF | c.684C>T p.L228= | Silent (SNP) | VAF 41/152 reads (27%) | catalogued as rs373712844; called by muse, mutect2, varscan2
- CDH23 | c.7773C>G p.L2591= | Silent (SNP) | VAF 41/144 reads (28%) | catalogued as COSV56462976; called by muse, mutect2, varscan2
- CEP295 | c.5787G>A p.V1929= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as rs1172219174; called by muse, mutect2, varscan2
- CMYA5 | c.11028G>A p.E3676= | Silent (SNP) | VAF 51/209 reads (24%) | called by muse, mutect2, varscan2
- DOCK4 | c.4638G>A p.L1546= | Silent (SNP) | VAF 41/120 reads (34%) | called by muse, mutect2, varscan2
- FOXA3 | c.180G>A p.L60= | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as COSV56216648; called by muse, mutect2, varscan2
- IGFLR1 | c.714G>C p.L238= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as rs753426379; called by muse, mutect2, varscan2
- KMT2B | c.3210C>G p.L1070= | Silent (SNP) | VAF 61/181 reads (34%) | catalogued as COSV55866399; called by muse, mutect2, varscan2
- KMT2B | c.3405C>G p.L1135= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as rs1315306655; called by muse, mutect2, varscan2
- KMT2B | c.5844C>G p.V1948= | Silent (SNP) | VAF 63/197 reads (32%) | called by muse, mutect2, varscan2
- MYH7 | c.4440G>A p.E1480= | Silent (SNP) | VAF 50/166 reads (30%) | catalogued as COSV62519027; called by muse, mutect2, varscan2
- OR10J5 | c.144C>A p.I48= | Silent (SNP) | VAF 42/273 reads (15%) | catalogued as COSV58385720, COSV58387096; called by muse, mutect2, varscan2
- P4HA2 | c.399C>G p.A133= | Silent (SNP) | VAF 27/102 reads (26%) | called by muse, mutect2, varscan2
- PCBD1 | c.129C>T p.F43= | Silent (SNP) | VAF 50/173 reads (29%) | called by muse, mutect2, varscan2
- PPP2R5C | c.258G>C p.V86= | Silent (SNP) | VAF 27/71 reads (38%) | called by muse, mutect2
- RSPH14 | c.699C>A p.I233= | Silent (SNP) | VAF 66/176 reads (38%) | called by muse, mutect2, varscan2
- SIM2 | c.1878C>T p.P626= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- SLC4A5 | c.2805C>T p.F935= | Silent (SNP) | VAF 33/160 reads (21%) | called by muse, mutect2, varscan2
- SNAPC4 | c.174C>T p.I58= | Silent (SNP) | VAF 32/138 reads (23%) | catalogued as rs749143015; called by muse, mutect2, varscan2
- TMEM245 | c.1905C>T p.F635= | Silent (SNP) | VAF 55/215 reads (26%) | called by muse, mutect2, varscan2
- TNC | c.6462G>A p.L2154= | Silent (SNP) | VAF 36/157 reads (23%) | catalogued as rs1429925203; called by muse, mutect2, varscan2
- TNFSF14 | c.345G>A p.E115= | Silent (SNP) | VAF 18/72 reads (25%) | called by muse, mutect2
- ZBTB32 | c.198C>A p.I66= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV52892174; called by muse, mutect2, varscan2
- ZNF219 | c.1134C>G p.L378= | Silent (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- AASDHPPT | c.*1445G>A | 3'UTR (SNP) | VAF 30/85 reads (35%) | called by muse, mutect2, varscan2
- AC004899.2 | chr7:48846729 A>G | 5'Flank (SNP) | VAF 24/119 reads (20%) | called by muse, mutect2, varscan2
- AC112484.1 | n.820C>T | RNA (SNP) | VAF 34/137 reads (25%) | catalogued as rs1274125360; called by muse, mutect2, varscan2
- ACSS1 | c.*660C>A | 3'UTR (SNP) | VAF 16/58 reads (28%) | called by muse, mutect2, varscan2
- ADAMTS4 | c.*833T>A | 3'UTR (SNP) | VAF 10/75 reads (13%) | called by mutect2, varscan2
- AGO4 | c.*776del | 3'UTR (DEL) | VAF 20/64 reads (31%) | catalogued as rs149653098; called by mutect2, varscan2
- AKAP6 | c.3148-1286T>C | Intron (SNP) | VAF 37/96 reads (39%) | called by muse, mutect2, varscan2
- ALDH7A1 | c.193-762A>C | Intron (SNP) | VAF 49/245 reads (20%) | called by muse, mutect2, varscan2
- ANKLE2 | c.1700+70C>T | Intron (SNP) | VAF 20/68 reads (29%) | called by muse, mutect2
- ASPM | c.-227C>T | 5'UTR (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- ATP6V1C1 | c.*3404C>G | 3'UTR (SNP) | VAF 38/84 reads (45%) | called by muse, varscan2
- ATXN1 | c.*433C>T | 3'UTR (SNP) | VAF 60/220 reads (27%) | called by muse, mutect2, varscan2
- AZIN1 | c.*1931G>T | 3'UTR (SNP) | VAF 14/61 reads (23%) | called by muse, mutect2, varscan2
- BMP8B | c.*589G>A | 3'UTR (SNP) | VAF 30/83 reads (36%) | called by muse, mutect2, varscan2
- C20orf96 | c.*261C>T | 3'UTR (SNP) | VAF 6/31 reads (19%) | called by mutect2, varscan2
- C2CD5 | c.-12G>A | 5'UTR (SNP) | VAF 81/318 reads (25%) | catalogued as rs779130024; called by muse, mutect2, varscan2
- CACNG8 | c.*3973G>C | 3'UTR (SNP) | VAF 32/139 reads (23%) | called by muse, mutect2, varscan2
- CBX3 | c.*974C>A | 3'UTR (SNP) | VAF 104/794 reads (13%) | called by muse, mutect2, varscan2
- CCDC85C | c.*8258C>G | 3'UTR (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- CCL22 | c.*1925G>C | 3'UTR (SNP) | VAF 35/67 reads (52%) | catalogued as rs904742843; called by muse, mutect2, varscan2
- CCNP | c.*819C>G | 3'UTR (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- CD200R1 | c.*305G>T | 3'UTR (SNP) | VAF 24/106 reads (23%) | called by muse, mutect2, varscan2
- CDCA7 | c.*754del | 3'UTR (DEL) | VAF 26/85 reads (31%) | called by mutect2, pindel, varscan2
- CDON | c.*1219G>A | 3'UTR (SNP) | VAF 16/60 reads (27%) | catalogued as rs956910059; called by muse, mutect2, varscan2
- CFAP44 | c.*832T>C | 3'UTR (SNP) | VAF 23/109 reads (21%) | called by muse, mutect2, varscan2
- CHML | c.*3065T>C | 3'UTR (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- CHRM3 | c.*5143T>C | 3'UTR (SNP) | VAF 27/102 reads (26%) | called by muse, mutect2, varscan2
- CLDND1 | c.*525A>C | 3'UTR (SNP) | VAF 26/123 reads (21%) | called by muse, mutect2, varscan2
- CLIP2 | c.*1334G>A | 3'UTR (SNP) | VAF 50/162 reads (31%) | called by muse, mutect2, varscan2
- COL5A1 | c.*1866G>A | 3'UTR (SNP) | VAF 74/284 reads (26%) | called by muse, varscan2
- CTC1 | c.*21G>A | 3'UTR (SNP) | VAF 27/68 reads (40%) | called by muse, mutect2, varscan2
- CXCR2 | c.*713G>C | 3'UTR (SNP) | VAF 22/66 reads (33%) | called by muse, mutect2, varscan2
- DCAF6 | c.-79G>C | 5'UTR (SNP) | VAF 22/72 reads (31%) | catalogued as rs1245681197; called by mutect2, varscan2
- DCHS2 | n.3608C>A | RNA (SNP) | VAF 52/178 reads (29%) | called by muse, mutect2, varscan2
- DCP2 | c.*2786G>A | 3'UTR (SNP) | VAF 30/127 reads (24%) | called by muse, mutect2, varscan2
- DCUN1D1 | c.*3997G>C | 3'UTR (SNP) | VAF 27/108 reads (25%) | called by muse, mutect2, varscan2
- DDX51 | c.1251-34G>C | Intron (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- DENND3 | c.3396+54G>A | Intron (SNP) | VAF 39/117 reads (33%) | called by muse, mutect2, varscan2
- DIS3 | c.*3092C>T | 3'UTR (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- DMRT1 | c.*649G>C | 3'UTR (SNP) | VAF 7/140 reads (5%) | catalogued as rs1362388858; called by muse, mutect2
- DNAJB1P1 | n.590G>A | RNA (SNP) | VAF 15/62 reads (24%) | catalogued as rs776167410; called by muse, mutect2, varscan2
- DOK1 | c.-623C>T | 5'UTR (SNP) | VAF 34/167 reads (20%) | called by muse, mutect2, varscan2
- DYSF | c.88+12801G>A | Intron (SNP) | VAF 38/154 reads (25%) | catalogued as rs972675695; ClinVar: likely benign; called by muse, mutect2, varscan2
- EGFLAM | c.*233G>A | 3'UTR (SNP) | VAF 27/130 reads (21%) | called by muse, mutect2, varscan2
- EPB41L1 | c.*2548C>T | 3'UTR (SNP) | VAF 58/190 reads (31%) | called by muse, mutect2, varscan2
- EPB41L4B | c.*2526A>T | 3'UTR (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- ERCC8 | chr5:60873801 C>T | 3'Flank (SNP) | VAF 10/43 reads (23%) | catalogued as rs915542586; called by muse, mutect2, varscan2
- FADS1 | c.376-201C>T | Intron (SNP) | VAF 19/69 reads (28%) | catalogued as rs1053873018; called by muse, mutect2, varscan2
- FBXO7 | c.-19C>T | 5'UTR (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- FN1 | c.*6C>G | 3'UTR (SNP) | VAF 82/303 reads (27%) | called by muse, mutect2, varscan2
- FOXD1 | c.*13A>G | 3'UTR (SNP) | VAF 20/80 reads (25%) | called by muse, mutect2, varscan2
- FUZ | c.690+25G>A | Intron (SNP) | VAF 35/156 reads (22%) | called by muse, mutect2, varscan2
- GAPT | c.*750C>T | 3'UTR (SNP) | VAF 23/136 reads (17%) | called by mutect2, varscan2
- GASAL1 | n.730T>C | RNA (SNP) | VAF 47/134 reads (35%) | catalogued as rs1178017023; called by muse, mutect2, varscan2
- GPATCH2 | c.*3837G>A | 3'UTR (SNP) | VAF 23/108 reads (21%) | called by muse, mutect2, varscan2
- GXYLT2 | c.*1736A>T | 3'UTR (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2
- HEPH | c.-134G>A | 5'UTR (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- HHIP | c.*2466G>T | 3'UTR (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- HINFP | c.*936G>A | 3'UTR (SNP) | VAF 27/83 reads (33%) | called by muse, mutect2, varscan2
- HOOK3 | c.*9468C>G | 3'UTR (SNP) | VAF 28/89 reads (31%) | called by muse, mutect2, varscan2
- HUNK | c.*4805G>C | 3'UTR (SNP) | VAF 39/118 reads (33%) | called by muse, mutect2, varscan2
- IGFLR1 | c.*30A>C | 3'UTR (SNP) | VAF 14/51 reads (27%) | called by muse, varscan2
- IL1RAP | c.*974G>A | 3'UTR (SNP) | VAF 33/134 reads (25%) | called by muse, mutect2, varscan2
- IMPACT | c.*366C>G | 3'UTR (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- INSL5 | c.*250T>A | 3'UTR (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- IRAK3 | c.*3647G>A | 3'UTR (SNP) | VAF 34/86 reads (40%) | called by muse, varscan2
- KBTBD8 | c.*508_*525del | 3'UTR (DEL) | VAF 12/70 reads (17%) | called by mutect2, pindel, varscan2
- KCND3 | chr1:111772916 C>T | 3'Flank (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- KIFC3 | c.316-2559C>T | Intron (SNP) | VAF 20/34 reads (59%) | called by muse, mutect2, varscan2
- KLHL13 | c.99-1010C>A | Intron (SNP) | VAF 17/24 reads (71%) | called by muse, mutect2, varscan2
- LIN54 | c.*2545C>G | 3'UTR (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- LRATD2 | c.*1152C>T | 3'UTR (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- MAP6 | c.-368T>A | 5'UTR (SNP) | VAF 22/86 reads (26%) | called by muse, mutect2, varscan2
- MCOLN3 | c.*470A>G | 3'UTR (SNP) | VAF 10/43 reads (23%) | called by mutect2, varscan2
- MIR1915 | chr10:21495823 G>A | 3'Flank (SNP) | VAF 21/68 reads (31%) | catalogued as rs1420782692; called by muse, mutect2, varscan2
- MTCL1 | chr18:8831656 G>A | 3'Flank (SNP) | VAF 16/378 reads (4%) | called by muse, mutect2
- MYADML2 | c.*1110C>T | 3'UTR (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
- MYO15A | c.8788+48C>T | Intron (SNP) | VAF 54/148 reads (36%) | catalogued as rs1015170607; called by muse, mutect2, varscan2
- NAA60 | c.572+22G>A | Intron (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2
- NAB1 | c.*968G>C | 3'UTR (SNP) | VAF 13/41 reads (32%) | catalogued as rs915115320; called by muse, mutect2, varscan2
- NEBL | c.*243C>T | 3'UTR (SNP) | VAF 31/95 reads (33%) | catalogued as COSV101009163; called by muse, mutect2
- NEUROD4 | c.*1462C>T | 3'UTR (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- NHLH2 | chr1:115843909 G>A | 5'Flank (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- NKX2-4 | c.*205A>G | 3'UTR (SNP) | VAF 22/74 reads (30%) | called by muse, mutect2, varscan2
- OLFML2A | c.670-480C>T | Intron (SNP) | VAF 38/189 reads (20%) | called by muse, mutect2, varscan2
- ORC2 | c.1148-51G>A | Intron (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- OTOAP1 | n.1375C>T | RNA (SNP) | VAF 31/244 reads (13%) | catalogued as rs1366395028; called by muse, mutect2, varscan2
- P2RX6 | chr22:21011505 C>T | 5'Flank (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- PAWR | c.*1780A>G | 3'UTR (SNP) | VAF 19/70 reads (27%) | called by muse, mutect2, varscan2
- PDCD10 | c.*263C>T | 3'UTR (SNP) | VAF 27/127 reads (21%) | called by muse, mutect2, varscan2
- PDGFD | c.*643C>G | 3'UTR (SNP) | VAF 33/93 reads (35%) | called by muse, mutect2, varscan2
- PFKFB4 | c.988-26G>A | Intron (SNP) | VAF 46/150 reads (31%) | catalogued as rs745489743; called by muse, varscan2
- PGAM1 | c.-15C>G | 5'UTR (SNP) | VAF 26/69 reads (38%) | called by muse, mutect2, varscan2
- PKP2 | c.*775A>G | 3'UTR (SNP) | VAF 20/64 reads (31%) | catalogued as rs543832696; called by muse, mutect2, varscan2
- PLPP5 | c.463+180C>G | Intron (SNP) | VAF 26/78 reads (33%) | called by muse, varscan2
- PSD | c.2556-81C>T | Intron (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- PSMA3 | c.590+154G>T | Intron (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- PSMA8 | c.496-8098C>T | Intron (SNP) | VAF 61/201 reads (30%) | called by muse, mutect2, varscan2
- PTGDR | c.*642G>C | 3'UTR (SNP) | VAF 28/95 reads (29%) | called by muse, mutect2, varscan2
- RAN | chr12:130876608 A>G | 3'Flank (SNP) | VAF 12/38 reads (32%) | catalogued as rs938153598; called by mutect2, varscan2
- RGS4 | c.*854G>A | 3'UTR (SNP) | VAF 24/178 reads (13%) | catalogued as rs1177725564; called by muse, varscan2
- RGS7BP | c.333-9C>T | Intron (SNP) | VAF 30/155 reads (19%) | called by muse, mutect2, varscan2
- RUNX1 | c.*1761G>A | 3'UTR (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- SCN3B | c.*2435C>T | 3'UTR (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- SERINC1 | c.*1671C>G | 3'UTR (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- SGMS2 | chr4:107912008 G>A | 3'Flank (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- SLC44A1 | c.*2472A>G | 3'UTR (SNP) | VAF 25/95 reads (26%) | called by muse, mutect2, varscan2
- SLC9A2 | c.*1933C>T | 3'UTR (SNP) | VAF 15/122 reads (12%) | called by mutect2, varscan2
- SORL1 | c.*1419C>T | 3'UTR (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- SPAG9 | c.*635C>T | 3'UTR (SNP) | VAF 30/115 reads (26%) | called by muse, mutect2, varscan2
- SPEF2 | c.2839+1445G>C | Intron (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- STT3B | chr3:31532918 C>T | 5'Flank (SNP) | VAF 31/99 reads (31%) | catalogued as rs1432448887; called by muse, mutect2, varscan2
- TAZ | c.284+44C>T | Intron (SNP) | VAF 19/70 reads (27%) | catalogued as rs1488804193; called by muse, mutect2, varscan2
- TBX5 | c.*16A>T | 3'UTR (SNP) | VAF 82/262 reads (31%) | called by muse, varscan2
- TIMM17A | c.*1024G>C | 3'UTR (SNP) | VAF 16/100 reads (16%) | called by muse, mutect2
- TIMM50 | chr19:39480746 C>T | 5'Flank (SNP) | VAF 59/231 reads (26%) | catalogued as rs148405081; called by muse, mutect2, varscan2
- TMEM38B | c.*2164C>T | 3'UTR (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- TMPRSS4 | c.*1082G>C | 3'UTR (SNP) | VAF 22/111 reads (20%) | called by muse, mutect2, varscan2
- TMPRSS6 | c.1196+264C>G | Intron (SNP) | VAF 12/36 reads (33%) | called by muse, varscan2
- TMPRSS6 | c.1196+202C>T | Intron (SNP) | VAF 9/28 reads (32%) | called by muse, varscan2
- TNFRSF14 | c.305-161C>T | Intron (SNP) | VAF 54/133 reads (41%) | called by muse, mutect2, varscan2
- TSC22D3 | c.*987G>C | 3'UTR (SNP) | VAF 35/54 reads (65%) | called by muse, mutect2, varscan2
- TUB | c.*3542C>T | 3'UTR (SNP) | VAF 34/129 reads (26%) | called by muse, mutect2, varscan2
- TUBGCP5 | c.*385G>A | 3'UTR (SNP) | VAF 5/35 reads (14%) | called by mutect2, varscan2
- TXLNGY | n.6240C>T | RNA (SNP) | VAF 36/55 reads (65%) | called by muse, mutect2, varscan2
- U2AF1L4 | c.*134G>T | 3'UTR (SNP) | VAF 65/159 reads (41%) | called by muse, mutect2, varscan2
- U2AF1L4 | c.-44G>T | 5'UTR (SNP) | VAF 31/75 reads (41%) | catalogued as COSV53074761; called by muse, mutect2, varscan2
- UBXN2A | c.287+118T>A | Intron (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- USH2A | c.7451+15T>G | Intron (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- WDR31 | c.*1009G>A | 3'UTR (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- XPR1 | c.1808+93G>C | Intron (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- ZAP70 | c.890-63G>A | Intron (SNP) | VAF 36/145 reads (25%) | called by muse, mutect2, varscan2
- ZDHHC22 | c.*937G>A | 3'UTR (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- ZFAND5 | c.*3619C>T | 3'UTR (SNP) | VAF 17/64 reads (27%) | catalogued as rs1015773440; called by muse, mutect2, varscan2
- ZNF396 | c.*1010A>T | 3'UTR (SNP) | VAF 17/62 reads (27%) | called by muse, mutect2, varscan2
- ZNF594 | c.*1621G>A | 3'UTR (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
